Somatic mutation profile of tumor specimen C3L-06803-54 (aliquot CPT0423400002) from CPTAC case C3L-06803, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 50.3 years (18,360 days).
Specimen C3L-06803-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 922b45f5-49b0-4fe5-8296-6225f82ce916.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06803-51 (Buccal Cell Normal), aliquot CPT0423430001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d7ecb3c-e7e8-40b7-8348-81680eb63de9

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 32/78 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2
- GPR37 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1329656008; called by muse, mutect2, varscan2
- SCN10A | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs377467259; called by mutect2, varscan2
- BCOR | c.2264dup p.Y755* | Nonsense Mutation (INS) | VAF 100/190 reads (53%) | called by mutect2, pindel, varscan2
- OTOL1 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKR1B1P6 | n.18C>T | RNA (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2
- D2HGDH | c.-41C>A | 5'UTR (SNP) | VAF 73/177 reads (41%) | catalogued as rs1483444611; called by muse, mutect2, varscan2
